Somatic mutation profile of tumor specimen 0DPE9J from CCDI case PBCDEM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.3 years (6,329 days).
Specimen 0DPE9J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d7b12b4-ee3d-4e3c-9047-731211694334.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPE92 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20511048-b80f-4dd1-b42d-f1704c232f9a

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Nonsense Mutation 4, Silent 4, Intron 4, Frame Shift Del 2, Splice Site 1, Splice Region 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP27B1 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555068245, CM126951, COSV56984293; ClinVar: likely pathogenic; called by muse, mutect2
- NIPBL | c.5044C>T p.R1682* | Nonsense Mutation (SNP) | VAF 37/691 reads (5%) | catalogued as rs797045769, COSV56944290; ClinVar: pathogenic; called by muse, mutect2
- AGRN | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 50/598 reads (8%) | catalogued as COSV101038600; called by muse, mutect2
- AJM1 | c.2449T>G p.S817A | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs372213172; called by muse, mutect2, varscan2
- AL441992.2 | c.1433A>G p.Y478C | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as rs75692348; called by muse, mutect2
- ASAP1 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100727956, COSV63048962; called by muse, mutect2, varscan2
- CERCAM | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 128/317 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571686461; called by muse, mutect2, varscan2
- CHST5 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781527035, COSV60336737; called by muse, mutect2
- GRM3 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446375, COSV64469346; called by muse, mutect2
- HERPUD2 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 54/755 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as rs187935009; called by muse, mutect2
- KLHL30 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 207/699 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs369875701; called by muse, mutect2, varscan2
- LIX1L | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 123/488 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs570209774; called by muse, mutect2, varscan2
- PRKACG | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 101/399 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV55260834; called by muse, mutect2, varscan2
- PUS10 | c.1451+1G>A p.X484_splice | Splice Site (SNP) | VAF 116/333 reads (35%) | catalogued as rs766402169, COSV57454972, COSV57455239; called by muse, mutect2, varscan2
- RUFY3 | c.14C>A p.T5K | Missense Mutation (SNP) | VAF 60/333 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs763445500; called by muse, mutect2, varscan2
- SPIDR | c.1783C>T p.H595Y | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.068); catalogued as COSV52371781; called by muse, mutect2, varscan2
- SRRM2 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs146277556; called by muse, mutect2, varscan2
- TOX3 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 30/272 reads (11%) | catalogued as COSV54863429, COSV54863946; called by mutect2, varscan2
- TP53 | c.540G>C p.E180D | Missense Mutation (SNP) | VAF 139/258 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52795798, COSV52950275, COSV53516148; called by muse, mutect2, varscan2
- TRHR | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 168/564 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs756257265; called by muse, mutect2, varscan2
- AGAP2 | c.1921C>G p.R641G (on ENST00000547588 / NM_001122772.2; = p.R305G on NM_014770.4) | Missense Mutation (SNP) | VAF 13/399 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- CHD7 | c.7921_7922del p.L2641Dfs*11 | Frame Shift Del (DEL) | VAF 159/495 reads (32%) | called by mutect2, pindel, varscan2
- DHDH | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MAP3K6 | c.1712C>A p.P571Q | Missense Mutation (SNP) | VAF 125/510 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NAT16 | c.312+6C>T | Splice Region (SNP) | VAF 89/284 reads (31%) | called by muse, mutect2, varscan2
- OR2B6 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 141/429 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PCDHA4 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 121/540 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); called by muse, varscan2
- PID1 | c.544T>C p.W182R (on ENST00000354069 / NM_001330156.1; = p.W180R on NM_017933.5) | Missense Mutation (SNP) | VAF 104/407 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCL2 | c.1231T>C p.S411P (on ENST00000615277 / NM_001144382.2; = p.S285P on NM_015184.5) | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PRPS1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 92/257 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PTCH1 | c.3114C>A p.C1038* | Nonsense Mutation (SNP) | VAF 149/562 reads (27%) | called by muse, mutect2, varscan2
- PTCH1 | c.2178del p.C727Vfs*19 | Frame Shift Del (DEL) | VAF 92/373 reads (25%) | called by mutect2, pindel, varscan2
- RB1CC1 | c.1937C>T p.T646I | Missense Mutation (SNP) | VAF 100/253 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CUL7 | c.246G>C p.L82= | Silent (SNP) | VAF 117/427 reads (27%) | called by muse, mutect2, varscan2
- OR5H15 | c.801A>T p.A267= | Silent (SNP) | VAF 96/572 reads (17%) | catalogued as rs151289674, COSV62947301; called by muse, mutect2, varscan2
- PRAMEF27 | c.456C>T p.F152= | Silent (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- SLC1A4 | c.396C>T p.A132= | Silent (SNP) | VAF 8/186 reads (4%) | catalogued as rs1385150933; called by muse, mutect2
- CHEK1 | c.718+65A>T | Intron (SNP) | VAF 38/147 reads (26%) | called by muse, mutect2, varscan2
- COL14A1 | c.5312-73C>G | Intron (SNP) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- FAM193A | c.439-2774A>G | Intron (SNP) | VAF 32/352 reads (9%) | called by muse, mutect2
- SOGA1 | c.*8773C>T | 3'UTR (SNP) | VAF 53/160 reads (33%) | catalogued as rs780050524; called by muse, mutect2, varscan2
- TAZ | c.238+83C>T | Intron (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- TOMM5 | c.-50A>T | 5'UTR (SNP) | VAF 20/319 reads (6%) | called by muse, mutect2
